TCGA case TCGA-HD-8634 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22933e67-5c61-4c13-9772-5adb78785b34

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Dead; Days to death: 385 days (1.1 years); Cause of death: Not Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.2 years (18,718 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 385 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 4; Lymphatic invasion present: No; Margin status: Uninvolved; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 24 days; Treatment outcome: No Measurable Disease.
2. Prior malignancy of the cervix uteri (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 24.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60; Tobacco smoking onset year: 1979.
- Alcohol history: Yes; Alcohol drinks per day: 7; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HD-8634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-HD-8634-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-HD-8634-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HD-8634-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: No; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; Cause of death: Other, non-malignant disease; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Cervix.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy cervical cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 385 days; disease-specific survival: no event (censored), 385 days; disease-free interval: no event (censored), 385 days; progression-free interval: no event (censored), 385 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HD-8634-01A-11D-2390-01): tumor purity 0.32, ploidy 1.9, whole-genome doublings 0.
